Somatic mutation profile of tumor specimen TCGA-KK-A8I6-01A (aliquot TCGA-KK-A8I6-01A-11D-A364-08) from TCGA case TCGA-KK-A8I6, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.9 years (21,499 days).
Specimen TCGA-KK-A8I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6428f67-c45a-4ad7-8bdc-4a8cabf5d9de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8I6-11A (Solid Tissue Normal), aliquot TCGA-KK-A8I6-11A-12D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4d0fdff-c274-43d0-9382-70677f191dc5

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC011448.1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1025815225, COSV53063705, COSV99389240; called by muse, mutect2, varscan2
- AOX1 | c.3000T>G p.N1000K | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101022210; called by muse, mutect2
- CHD4 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100539068; called by muse, varscan2
- CSMD3 | c.11097C>A p.N3699K (on ENST00000297405 / NM_001363185.1; = p.N3530K on NM_052900.3) | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs891524968, COSV52199074; called by muse, mutect2, varscan2
- DYRK1B | c.1458C>G p.S486R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs754713659, COSV100546722; called by muse, mutect2, varscan2
- ESR1 | c.1688C>T p.T563M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs763337967, COSV52794526; called by muse, mutect2, varscan2
- FLNA | c.3308C>T p.T1103M | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781970327, COSV100775138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRAS1 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV99355388; called by muse, mutect2, varscan2
- GMPPB | c.166A>C p.M56L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100246734; called by muse, mutect2, varscan2
- GPR158 | c.397A>C p.T133P | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100894216; called by muse, mutect2
- LRP1B | c.9625G>A p.V3209I | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as rs77794732, COSV67231336, COSV67250866, COSV67284629; called by muse, mutect2, varscan2
- MDGA2 | c.904T>G p.F302V (on ENST00000399232 / NM_001113498.2; = p.F4V on NM_182830.4) | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV100638258; called by muse, mutect2, varscan2
- MKI67 | c.2824G>T p.D942Y | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100896931, COSV64074050; called by muse, mutect2, varscan2
- OR4A5 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as COSV100157271; called by muse, mutect2, varscan2
- PEX16 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as COSV99572373; called by muse, mutect2
- RAD54B | c.830A>G p.N277S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as rs774638198, COSV100280150; called by muse, mutect2, varscan2
- RAG1 | c.2200G>C p.D734H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100201118; called by muse, mutect2, varscan2
- TACC2 | c.7048T>G p.F2350V (on ENST00000334433; = p.F428V on NM_006997.4) | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99587628; called by muse, mutect2, varscan2
- ADGRG5 | c.1341A>T p.A447= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100446499; called by muse, mutect2, varscan2
- ARID2 | c.2970G>A p.S990= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs78234941; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAP4K4 | c.2472G>A p.E824= (on ENST00000347699 / NM_001242559.2; = p.E742= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100155811; called by muse, mutect2, varscan2
- MEFV | c.510C>T p.D170= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1234279922, COSV54818212; called by muse, mutect2
- METTL25 | c.1227T>C p.S409= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1325301214, COSV99942658; called by muse, mutect2, varscan2
- TLCD5 | c.7T>C p.L3= (on ENST00000375095 / NM_001198671.2; = p.L25= on NM_174926.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100081154; called by muse, mutect2, varscan2
- TMC4 | c.1224G>A p.P408= (on ENST00000617472 / NM_001145303.3; = p.P402= on NM_144686.4) | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs149954505; called by muse, mutect2, varscan2
- UBQLNL | c.315C>T p.G105= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV100975442; called by muse, mutect2
- AC024940.1 | n.3870G>A | RNA (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
